Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5851, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5851-01A (Primary Tumor).

[page 1 of 4]
TCGA--DU-5851

Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

=====

CLINICAL HISTORY

Brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, right temporal tip, excision biopsy
B: Brain, superior uncus, excision biopsy
C: Brain, right posterior parahippocampal gyrus, excision biopsy
D: Brain, superior temporal tumor, excision biopsy
E: Brain, superior medial temporal, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A., B, D. and E. Brain, right temporal lesion, excision biopsy:
Anaplastic
oligoastrocytoma (WHO Grade III) (see comment).
C. Brain, right posterior parahippocampal gyrus, excision biopsy:
Temporal
lobe with hippocampal dentate gyrus and no definite tumor.

COMMENT

Permanent sections confirm the diagnosis of glioma. Sections show a moderately pleomorphic astrocytoma with gemistocytic features. Some areas show more round shaped tumor cell nuclei. Occasional apoptotic cells and rare mitotic figures are noted. Definite vascular proliferation or necrosis are not seen. Immunohistochemical stains show that the tumor is diffusely and strongly p53 positive. The Ki-67 labeling index is approximately 7%. Positive and negative controls show appropriate immunoreactivity. Sections of C. show temporal lobe with hippocampal dentate gyrus and no definite tumor. Although the tumor appears to show mixed oligodendroglial and astrocytic morphology, the predominant component appears to be astrocytic.

[page 2 of 4]
=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Test performed on DNA extracted from tissue paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] as required by [REDACTED]. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

[REDACTED] at

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, right temporal tip, excision biopsy: Glioma (favor high-grade

[page 3 of 4]
astrocytic lesion). Frozen section and smears performed on specimen A.
at

[REDACTED]

[REDACTED]

GROSS DESCRIPTION

A. Brain, right temporal tip, excision biopsy: CONTAINER LABEL:
Right

temporal lobe

FIXATIVE: Formalin. NO. PIECES: multiple (5). SIZE/VOL: 15x10x2 mm.

CASSETTES: A1: FS remnant; A2: Remainder of the tissue.

B. Brain, superior uncus, excision biopsy: CONTAINER LABEL:
superior uncus.

FIXATIVE: Fresh. NO. PIECES: 2 tan-gray fragments. SIZE/VOL: 4 x2 x2
mm and

5 x5 x3 mm. CASSETTES: 1, NS.

C. Brain, right posterior parahippocampal gyrus, excision biopsy:
CONTAINER

LABEL: right post hippocampal gyrus.

FIXATIVE: fresh. NO. PIECES: few tan-gray friable fragments.

SIZE/VOL:

aggregate 7 x4 x3 mm. CASSETTES: 1, NS.

D. Brain, superior temporal tumor, excision biopsy: CONTAINER
LABEL:

superior temporal tumor.

FIXATIVE: Fresh. NO. PIECES: 2 tan-gray fragments. SIZE/VOL: 7 x6 x6
mm and

19 x6 x5 mm. CASSETTES: 1, NS, serially sectioned.

E. Brain, superior medial temporal, excision biopsy: CONTAINER LABEL:
superior medial temporal.

FIXATIVE: Fresh. NO. PIECES: 1 tan-gray. SIZE/VOL: 6 x5 x3 mm.

CASSETTES:

1, NS.

[REDACTED]

ICD-9(s):

191.9 191.9

[REDACTED]

Histo Data

Part A: Brain, right temporal tip, excision biopsy

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt

Block

Ordered

Comment

FS H/E x 1

1

[REDACTED]

[page 4 of 4]
H/E x 1	1	
MGMT-curly x 1	1	
MIB1-DA x 1	1	
P53DO7 x 1	1	
TPS H/E x 1	1	
H/E x 1	2	

Part B: Brain, superior uncus, excision biopsy

Received:		
Stain/cnt	Block	Ordered
H/E x 1	1	

Part C: Brain, right posterior parahippocampal gyrus, excision biopsy

Taken:	Received:	
	Block	Ordered
	1	

Part D: Brain, superior temporal tumor, excision biopsy

Taken:	Received:	
Stain/cnt	Block	Ordered
H/E x 1	1	

Part E: Brain, superior medial temporal, excision biopsy

Taken:	Received:	
Stain/cnt	Block	Ordered
H/E x 1	1	

*** End of Report ***

Source: NCI Genomic Data Commons file 4f11d23e-0e58-42f5-a6eb-39c02b47f3a3 (TCGA-DU-5851.BEB751ED-B79D-43DE-93B6-BCBBB47EA6F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).